Gene-level copy-number profile of tumor specimen TCGA-85-8351-01A from TCGA case TCGA-85-8351, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.4 years (26,437 days).
Specimen TCGA-85-8351-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.cc7f1041-7105-46ac-b0a7-97a95e121663.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8351-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af0ce09f-9828-436a-8642-084e3d4bd2c5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 21; copy number 2: 16,662; copy number 3: 33,164; copy number 4: 4,077; copy number 5: 4,197; copy number 6: 1,165; copy number 7: 231; copy number 8: 47; copy number 11: 39; copy number 12: 16; copy number 21: 80; copy number 26: 30; copy number 27: 35; copy number 56: 39; copy number 60: 1; copy number 64: 2; copy number 69: 1; copy number 75: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8351-01A-11D-2292-01): tumor purity 0.49, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 528 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,415,384–65,761,352, 126 genes, copy number 21–27 (broad region; genes not listed).
- chr1:87,620,803–88,685,204, 2 genes, copy number 8 (within-gene range 3–8): PKN2-AS1, AL445437.1.
- chr5:17,378,906–29,983,114, 144 genes, copy number 7 (broad region; genes not listed).
- chr6:104,487,095–110,476,641, 117 genes, copy number 7–12 (broad region; genes not listed).
- chr7:54,330,670–55,862,755, 39 genes, copy number 56 (within-gene range 3–56): LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr8:54,191,582–54,355,118, 4 genes, copy number 60–69: AC060764.1, AC044836.1, RNU105C, AC027250.1.
- chr8:127,289,817–127,742,951, 7 genes, copy number 75 (within-gene range 3–75): CASC8, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr13:102,263,046–102,896,033, 19 genes, copy number 21: RPL39P29, FGF14-IT1, AL356266.1, FGF14-AS1, FGF14-AS2, LINC00555, AL158063.1, TPP2, METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1.
- chr19:50,136,859–50,719,802, 25 genes, copy number 7 (within-gene range 5–7): AC010624.5, IZUMO2, MYH14, Metazoa_SRP, AC008655.1, KCNC3, NR1H2, NAPSB, NAPSA, AC008655.2, POLD1, AC020909.1, SPIB, MYBPC2, FAM71E1, EMC10, AC020909.3, AC020909.2, JOSD2, ASPDH, LRRC4B, AC008743.1, SYT3, C19orf81, SHANK1.
- chr19:55,947,832–56,626,481, 43 genes, copy number 8 (within-gene range 4–8): NLRP8, NLRP5, LINC01864, ZNF787, Y_RNA, AC024580.2, ZNF444, AC024580.1, GALP, ZSCAN5B, ZSCAN5C, AC011506.1, ZSCAN5A, ZSCAN5DP, EDDM13, AC006116.5, AC006116.7, Y_RNA, VN2R17P, AC006116.1, AC006116.3, AC006116.2, AC006116.6, AC006116.8, ZNF542P, ZNF582, AC006116.9, SLC25A36P1, AC006116.4, ZNF582-AS1, ZNF583, ZNF667, ZNF667-AS1, AC004696.2, AC004696.1, ZNF471, AC005498.1, AC005498.2, ZFP28, AC005498.3, ZNF470, SIGLEC31P, ZNF71.
- chr19:56,643,159–56,671,783, 2 genes, copy number 8: SMIM17, ZNF835.

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
